Somatic mutation profile of tumor specimen TCGA-MA-AA3Y-01A (aliquot TCGA-MA-AA3Y-01A-11D-A387-09) from TCGA case TCGA-MA-AA3Y, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 48.7 years (17,795 days).
Specimen TCGA-MA-AA3Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db757646-e8b4-4812-85c0-93265d76227b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MA-AA3Y-10A (Blood Derived Normal), aliquot TCGA-MA-AA3Y-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5fda64d-4636-4a86-8063-51a7c7867fb2

The open-access MAF lists 173 somatic variants for this specimen: 127 protein-altering or splice-affecting, 45 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 45, Nonsense Mutation 13, Splice Site 2, Frame Shift Del 2, Splice Region 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABI3BP | c.2114G>C p.R705T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV99428977; called by muse, mutect2, varscan2
- ACAD11 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.857); catalogued as rs1270010421, COSV99392860; called by muse, mutect2, varscan2
- ADH4 | c.984G>A p.W328* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99644452; called by muse, mutect2
- ADRA1A | c.903C>G p.F301L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99372700; called by muse, mutect2, varscan2
- ANAPC1 | c.832-1G>C p.X278_splice | Splice Site (SNP) | VAF 17/78 reads (22%) | catalogued as COSV100595206; called by muse, mutect2, varscan2
- ASB8 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as rs747598837, COSV58350916; called by muse, mutect2, varscan2
- ATP2B3 | c.2630C>T p.S877F | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99686262; called by muse, mutect2, varscan2
- AXDND1 | c.1170G>C p.M390I | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100858766, COSV62650411; called by muse, mutect2, varscan2
- BAZ2B | c.2964G>A p.K988= | Splice Region (SNP) | VAF 11/73 reads (15%) | catalogued as COSV99681111; called by muse, mutect2, varscan2
- BCOR | c.5030C>T p.S1677F (on ENST00000378444 / NM_001123385.2; = p.S1643F on NM_017745.6) | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV100654404; called by muse, mutect2, varscan2
- BEND3 | c.1833C>G p.I611M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV100944722; called by muse, mutect2
- BRD8 | c.1948C>G p.Q650E (on ENST00000254900 / NM_139199.2; = p.Q723E on NM_006696.4) | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.145); catalogued as COSV99137905; called by muse, mutect2, varscan2
- BTAF1 | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.913); catalogued as COSV99795961; called by muse, mutect2, varscan2
- C1orf122 | c.317G>C p.G106A | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100888725; called by muse, mutect2, varscan2
- CARD11 | c.1378C>G p.Q460E | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV62754226; called by muse, mutect2, varscan2
- CCDC47 | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99854387; called by muse, mutect2, varscan2
- CCDC87 | c.2371G>C p.E791Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as COSV59579158; called by mutect2, varscan2
- CCDC87 | c.2224G>C p.E742Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100040287; called by muse, mutect2, varscan2
- CCR9 | c.740C>T p.S247F (on ENST00000357632 / NM_031200.3; = p.S235F on NM_006641.4) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV100591805; called by muse, mutect2, varscan2
- CENPF | c.1938C>A p.H646Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV65273399; called by muse, mutect2, varscan2
- CIDEB | c.14C>G p.S5* | Nonsense Mutation (SNP) | VAF 12/77 reads (16%) | catalogued as COSV51865367; called by muse, mutect2, varscan2
- COL18A1 | c.4411G>A p.E1471K (on ENST00000359759 / NM_130444.3; = p.E1236K on NM_030582.4) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as rs944314178, COSV100645493; called by muse, varscan2
- COL6A6 | c.2017G>C p.E673Q | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as COSV100651116; called by muse, mutect2, varscan2
- CPLANE2 | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1003620441, COSV100983295; called by muse, mutect2, varscan2
- CRELD1 | c.351G>C p.E117D | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1315128883, COSV99926110; called by muse, mutect2, varscan2
- CRISPLD1 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as COSV100082583; called by muse, mutect2, varscan2
- CUBN | c.2651C>T p.S884F | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760592191, COSV100913757; called by muse, mutect2, varscan2
- CYP27A1 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV99298821; called by muse, mutect2, varscan2
- DHX34 | c.1663G>C p.E555Q | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV100170057; called by muse, mutect2, varscan2
- DOCK11 | c.5563G>C p.E1855Q | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99353530, COSV99355061; called by muse, mutect2
- DZIP1 | c.1394C>G p.S465C | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV100714215; called by muse, mutect2, varscan2
- ERG | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 14/76 reads (18%) | catalogued as COSV99902996; called by muse, mutect2, varscan2
- EXTL1 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV100959149; called by muse, mutect2, varscan2
- FAF1 | c.1479A>T p.E493D | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.072); catalogued as COSV100876418; called by muse, mutect2, varscan2
- FAM135B | c.4009C>A p.H1337N | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV99427533, COSV99428717; called by muse, mutect2, varscan2
- FAT4 | c.8033C>A p.S2678Y | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV58680838; called by muse, mutect2, varscan2
- FCRL5 | c.2381G>T p.G794V | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); catalogued as COSV100709441, COSV62521502; called by muse, mutect2, varscan2
- FILIP1 | c.3575C>T p.S1192F | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99386424; called by muse, mutect2, varscan2
- FKBP5 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs759431987, COSV100616480; called by muse, mutect2, varscan2
- FLI1 | c.1099C>G p.Q367E | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV55645513, COSV99858214; called by muse, mutect2, varscan2
- FREM2 | c.3301G>A p.D1101N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV99751595; called by muse, mutect2, varscan2
- GON4L | c.2067G>C p.K689N | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.169); catalogued as rs774659112, COSV99676204; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1554356319, COSV56085059; called by muse, mutect2, varscan2
- HAO2 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100378334; called by muse, mutect2, varscan2
- HERC1 | c.14563G>A p.E4855K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV71246566; called by muse, mutect2, varscan2
- HIVEP2 | c.3577C>G p.Q1193E | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.142); catalogued as COSV99177207; called by muse, mutect2, varscan2
- HS3ST3B1 | c.342G>C p.Q114H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100714607; called by muse, mutect2, varscan2
- HSD17B4 | c.355G>T p.D119Y (on ENST00000414835 / NM_001199291.3; = p.D94Y on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99819648, COSV99820295; called by muse, mutect2, varscan2
- HUWE1 | c.7864G>A p.E2622K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV99474929; called by muse, mutect2, varscan2
- ICAM5 | c.2096G>A p.G699E | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0.037); catalogued as COSV99703605; called by muse, mutect2, varscan2
- ILK | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as rs773362090, COSV100196704; called by muse, mutect2, varscan2
- INVS | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.073); catalogued as rs774692372, COSV99318466; called by muse, mutect2, varscan2
- IPO7 | c.21C>G p.I7M | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV101121859; called by muse, mutect2, varscan2
- ITGB1BP2 | c.552G>A p.W184* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99339228; called by muse, mutect2, varscan2
- KCNH2 | c.1177C>A p.P393T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV100061465; called by muse, mutect2, varscan2
- KLHL38 | c.768G>C p.K256N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV100384703; called by muse, mutect2, varscan2
- KLHL6 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.625); catalogued as rs757111409, COSV100384782, COSV100385143; called by muse, mutect2, varscan2
- KLHL8 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99911639; called by muse, mutect2, varscan2
- KMT2D | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV99986724; called by muse, mutect2, varscan2
- LAMC1 | c.2535G>C p.L845F | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.568); catalogued as COSV99280702; called by muse, varscan2
- LGALS14 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs1347974912, COSV62372311; called by muse, mutect2, varscan2
- LRBA | c.7135C>G p.L2379V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV100842212; called by muse, mutect2, varscan2
- LRP1B | c.5623C>T p.Q1875* | Nonsense Mutation (SNP) | VAF 15/72 reads (21%) | catalogued as COSV101262189; called by muse, mutect2, varscan2
- LRRC4C | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99537799, COSV99539587; called by muse, mutect2, varscan2
- MAGEB1 | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV100975148; called by muse, mutect2, varscan2
- MCM6 | c.2402G>A p.G801E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV51469760; called by muse, mutect2, varscan2
- MDC1 | c.1744G>C p.E582Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.702); catalogued as COSV100903168, COSV64522980; called by muse, mutect2
- MUC17 | c.7574C>T p.T2525M | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs759930857, COSV60301125; called by muse, mutect2, varscan2
- MYO15A | c.4018G>T p.E1340* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV52762178, COSV99234972; called by muse, mutect2, varscan2
- MYOM3 | c.3160A>G p.I1054V | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100142037; called by muse, mutect2, varscan2
- NAT8L | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV100527147; called by muse, mutect2, varscan2
- NBEA | c.3488C>G p.S1163C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as rs773592580, COSV100085135; called by muse, mutect2, varscan2
- NCKAP5 | c.3611G>T p.G1204V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV100494887; called by muse, mutect2, varscan2
- NOD1 | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs556139791, COSV99768619; called by muse, mutect2, varscan2
- NOTCH3 | c.6602C>T p.P2201L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV99659297; called by muse, mutect2, varscan2
- NOXA1 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 17/93 reads (18%) | catalogued as COSV100395784; called by muse, mutect2, varscan2
- NPRL2 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1188801230, COSV99206256; called by muse, mutect2, varscan2
- OLFM2 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1343565418, COSV53428240; called by muse, mutect2, varscan2
- OR2D3 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV100505184; called by muse, mutect2
- OR4C15 | c.205C>T p.L69F (on ENST00000314644; = p.L15F on NM_001001920.2) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.519); catalogued as COSV58951131; called by muse, mutect2, varscan2
- OR4Q3 | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59178150; called by muse, mutect2, varscan2
- PCDHGB6 | c.2260C>G p.L754V | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.081); catalogued as COSV99549630; called by muse, mutect2, varscan2
- PCLO | c.5887G>A p.D1963N | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.935); catalogued as COSV100439509; called by muse, mutect2, varscan2
- PDE2A | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.057); catalogued as COSV100558544; called by muse, mutect2, varscan2
- PEX14 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs778315559, COSV63062298; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PGAP6 | c.147C>G p.F49L | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as COSV99170899; called by muse, varscan2
- PHF24 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs749347715, COSV54273216; called by muse, mutect2, varscan2
- PIWIL1 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV99807056; called by muse, mutect2, varscan2
- PLXNB3 | c.4269G>A p.M1423I | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as rs970937749, COSV100738061; called by muse, mutect2, varscan2
- POU6F1 | c.1007C>G p.S336* | Nonsense Mutation (SNP) | VAF 24/85 reads (28%) | catalogued as COSV100374939; called by muse, mutect2, varscan2
- PRDM16 | c.2378C>G p.S793W | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV54595381, COSV99579591; called by muse, mutect2, varscan2
- PSD2 | c.959G>T p.R320L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV51197075, COSV51197165; called by muse, mutect2, varscan2
- PTPN12 | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50378393; called by muse, mutect2, varscan2
- RAD9A | c.231G>A p.M77I | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV100335109; called by muse, mutect2, varscan2
- RAP1B | c.371G>C p.R124T | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99164958; called by muse, mutect2, varscan2
- RGN | c.291G>C p.K97N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100282575; called by muse, mutect2, varscan2
- SCAF11 | c.2491C>G p.Q831E | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV65475127; called by muse, mutect2, varscan2
- SCN9A | c.4709G>A p.R1570K (on ENST00000303354; = p.R1559K on NM_002977.3) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100314642; called by muse, mutect2, varscan2
- SDF2L1 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as COSV99963695; called by muse, mutect2, varscan2
- SEMA5B | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV52089433; called by muse, mutect2, varscan2
- SERPINB2 | c.642G>C p.K214N | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.104); catalogued as COSV100208745; called by muse, mutect2, varscan2
- SLC6A9 | c.1686G>T p.M562I (on ENST00000360584 / NM_201649.4; = p.M508I on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as COSV100746591; called by muse, mutect2, varscan2
- SMC2 | c.2521G>A p.E841K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as COSV53954686, COSV99659942; called by muse, mutect2, varscan2
- SNAPC4 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as rs1391116651; called by muse, mutect2, varscan2
- SORBS2 | c.2428C>T p.R810C | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.115); catalogued as rs749449977, COSV99513301; called by muse, mutect2, varscan2
- TFAP2A | c.238G>A p.D80N (on ENST00000482890; = p.D72N on NM_001032280.3) | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100117283; called by muse, mutect2, varscan2
- TFDP2 | c.514G>A p.D172N (on ENST00000489671 / NM_001178139.2; = p.D111N on NM_006286.5) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.955); catalogued as COSV100051279; called by muse, mutect2, varscan2
- TGFB2 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | catalogued as COSV100860538; called by muse, mutect2, varscan2
- TMCO2 | c.177C>G p.F59L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.319); catalogued as COSV101033869; called by muse, mutect2, varscan2
- TNC | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100406480; called by muse, mutect2, varscan2
- TNFRSF11B | c.894G>C p.L298F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99817101; called by muse, mutect2, varscan2
- TRMT2B | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV100105569; called by muse, mutect2, varscan2
- VGLL4 | c.26C>G p.S9C | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs776106266, COSV99810594; called by muse, mutect2, varscan2
- VPS13B | c.4043-1G>C p.X1348_splice | Splice Site (SNP) | VAF 13/105 reads (12%) | catalogued as COSV100664066; called by muse, mutect2, varscan2
- WDR6 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.347); catalogued as rs1160832608, COSV100556796; called by muse, mutect2
- ZDHHC6 | c.347G>C p.R116T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101024488; called by muse, mutect2, varscan2
- ZFX | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.596); catalogued as COSV100458224; called by muse, mutect2, varscan2
- ZIM3 | c.317C>G p.S106* | Nonsense Mutation (SNP) | VAF 21/95 reads (22%) | catalogued as COSV99518901; called by muse, mutect2, varscan2
- ZNF222 | c.1128G>C p.K376N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99496710; called by muse, mutect2, varscan2
- ZNF251 | c.138G>C p.E46D | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV99478969; called by muse, mutect2, varscan2
- ZNF627 | c.1119T>G p.S373R | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.384); catalogued as COSV100741547; called by muse, mutect2, varscan2
- ZNF761 | c.869G>C p.R290T | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.59); catalogued as COSV100483555, COSV61887537; called by muse, mutect2, varscan2
- CARMIL2 | c.2817+3_2817+6dup | Frame Shift Ins (INS) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- CBR3 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.387); called by muse, mutect2
- HDAC2 | c.883_884del p.P295Ifs*13 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.2446_2449dup p.C817* | Nonsense Mutation (INS) | VAF 34/68 reads (50%) | called by mutect2, pindel, varscan2
- TRIP12 | c.2501_2502del p.F834Yfs*2 | Frame Shift Del (DEL) | VAF 19/69 reads (28%) | called by mutect2, pindel, varscan2
- AK9 | c.3096C>G p.L1032= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV100394530; called by muse, mutect2, varscan2
- ANO2 | c.1719C>T p.V573= (on ENST00000356134 / NM_001278597.3; = p.V577= on NM_001278596.3) | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV59010751; called by muse, mutect2, varscan2
- ANO2 | c.660G>A p.K220= (on ENST00000356134 / NM_001278597.3; = p.K224= on NM_001278596.3) | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100502690; called by muse, mutect2, varscan2
- AP3D1 | c.52C>T p.L18= | Silent (SNP) | VAF 33/157 reads (21%) | catalogued as rs752770647, COSV61427130; called by muse, mutect2, varscan2
- AQP1 | c.264G>A p.Q88= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100311079; called by muse, mutect2, varscan2
- CST9 | c.222G>C p.L74= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100980510; called by muse, mutect2, varscan2
- DDX19A | c.681C>G p.L227= | Silent (SNP) | VAF 28/125 reads (22%) | catalogued as rs1408033572, COSV56358836; called by muse, mutect2, varscan2
- DNMT1 | c.1659C>T p.H553= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs777372271, COSV100533235; ClinVar: likely benign; called by muse, mutect2, varscan2
- DRAP1 | c.99G>A p.A33= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV56988282; called by muse, mutect2, varscan2
- DYNC2I1 | c.2214G>A p.L738= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs979714113, COSV101337754; called by muse, mutect2, varscan2
- FREM2 | c.567C>T p.V189= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs370371340; called by muse, mutect2, varscan2
- GRIPAP1 | c.114C>T p.L38= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV100904430, COSV64551071; called by muse, mutect2, varscan2
- HHEX | c.495C>T p.P165= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs767789592, COSV99263065; called by muse, mutect2, varscan2
- HIPK2 | c.1500C>T p.F500= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as COSV61229025; called by muse, mutect2, varscan2
- HSP90AA1 | c.133C>T p.L45= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs11547522, COSV53488551, COSV99355590; called by muse, mutect2, varscan2
- HSPA8 | c.1239C>T p.L413= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs1319984868, COSV99914703; called by muse, mutect2, varscan2
- JARID2 | c.2289C>T p.G763= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs750878402, COSV59187560; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1467C>T p.F489= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs370671042; called by muse, mutect2, varscan2
- KIF14 | c.2106C>T p.V702= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as COSV100951134; called by muse, mutect2, varscan2
- KLHL38 | c.516G>C p.L172= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100384706; called by muse, mutect2, varscan2
- KLHL38 | c.231G>C p.L77= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100384709; called by muse, mutect2, varscan2
- LAPTM4B | c.516C>T p.L172= (on ENST00000445593; = p.L81= on NM_018407.6) | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as rs1186020125, COSV101503512; called by muse, mutect2, varscan2
- LDB3 | c.504G>A p.L168= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV99555634, COSV99556096; called by muse, mutect2, varscan2
- LSAMP | c.303G>T p.V101= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV100373406; called by muse, mutect2, varscan2
- LUZP1 | c.1278C>T p.F426= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100035602; called by muse, mutect2, varscan2
- MMP24 | c.1473C>T p.F491= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV55772184; called by muse, mutect2, varscan2
- MPDZ | c.4509C>T p.L1503= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs375006043; called by muse, mutect2, varscan2
- MUC16 | c.5079C>T p.I1693= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs1391237610, COSV101202288; called by muse, mutect2, varscan2
- MYH15 | c.4887G>A p.K1629= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV99844581; called by muse, mutect2, varscan2
- NCOA1 | c.994T>C p.L332= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99947386; called by muse, mutect2, varscan2
- NF1 | c.1479C>G p.L493= | Silent (SNP) | VAF 88/280 reads (31%) | catalogued as rs139653388; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR5B12 | c.183C>G p.L61= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100222611; called by muse, mutect2, varscan2
- PDIA6 | c.43C>T p.L15= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV99694998; called by muse, mutect2, varscan2
- PLEC | c.11295G>A p.K3765= (on ENST00000322810 / NM_201380.4; = p.K3655= on NM_000445.5) | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV100520059; called by muse, mutect2, varscan2
- RHOA | c.417G>A p.V139= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs762388328, COSV69042726; called by muse, mutect2, varscan2
- RYR3 | c.6324G>A p.Q2108= | Silent (SNP) | VAF 26/137 reads (19%) | catalogued as COSV101215225; called by muse, mutect2, varscan2
- SHH | c.39C>T p.V13= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as rs745751480, COSV51918662, COSV99793637; called by muse, mutect2, varscan2
- SIGLEC6 | c.729C>T p.I243= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV100585848; called by muse, mutect2, varscan2
- SLC24A1 | c.3150C>T p.L1050= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs1286882049, COSV56054724; called by muse, mutect2, varscan2
- SLC9A8 | c.922C>T p.L308= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs780562016, COSV100846361; called by muse, mutect2, varscan2
- SPEF2 | c.3147G>A p.L1049= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV61544009; called by muse, mutect2, varscan2
- TPO | c.954C>T p.N318= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs946585048, COSV100222528; called by muse, mutect2, varscan2
- TRAF7 | c.258C>A p.S86= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100399898; called by muse, mutect2, varscan2
- UNC13A | c.4326C>G p.L1442= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV53190510, COSV99409979; called by muse, mutect2, varscan2
- UXS1 | c.666G>A p.V222= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV99308959; called by muse, mutect2, varscan2
- EIF3B | c.*129G>A | 3'UTR (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100703923; called by muse, mutect2, varscan2
